Gene-level copy-number profile of tumor specimen TCGA-G4-6311-01A from TCGA case TCGA-G4-6311, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage III; Age at diagnosis: 80.2 years (29,297 days).
Specimen TCGA-G4-6311-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.f3b64ea5-f0cf-4e28-b350-16c437832996.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6311-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/20812d84-ef76-4cbb-ac01-690b7a3b3610

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,449; copy number 2: 31,734; copy number 3: 20,693; copy number 4: 1,993; copy number 5: 659; copy number 6: 1,883; copy number 7: 409.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6311-01A-11D-1717-01): tumor purity 0.41, ploidy 2.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,951 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:235,547,685–242,773,103, 114 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:40,153,482–51,015,165, 165 genes, copy number 5–6 (broad region; genes not listed).
- chr8:52,110,839–52,745,843, 8 genes, copy number 5: ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1.
- chr8:57,855,500–63,014,000, 66 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:99,013,266–99,877,580, 1 gene, copy number 7 (within-gene range 3–7): VPS13B.
- chr8:99,340,305–103,230,305, 104 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:103,154,614–103,154,689, 1 gene, copy number 6: MIR3151.
- chr8:107,160,354–118,622,112, 86 genes, copy number 5–6 (broad region; genes not listed).
- chr8:123,851,987–128,564,679, 82 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:131,129,761–133,902,407, 38 genes, copy number 5–6: AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1.
- chr8:135,859,369–137,092,183, 1 gene, copy number 5 (within-gene range 3–5): LINC02055.
- chr8:136,237,236–145,066,685, 223 genes, copy number 5 (broad region; genes not listed).
- chr13:18,467,172–45,851,753, 548 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr13:112,322,567–114,337,626, 62 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:87,250–16,053,197, 290 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:15,552,157–64,313,132, 1,162 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,444. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
